Somatic mutation profile of tumor specimen TCGA-IR-A3LH-01A (aliquot TCGA-IR-A3LH-01A-21D-A20U-09) from TCGA case TCGA-IR-A3LH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G4; Age at diagnosis: 49.6 years (18,118 days).
Specimen TCGA-IR-A3LH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ac445b9-c23b-4eff-be1b-a123a00cf4ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LH-10A (Blood Derived Normal), aliquot TCGA-IR-A3LH-10A-01D-A20U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d46ae3d4-4f19-44fd-a429-e03483146730

The open-access MAF lists 889 somatic variants for this specimen: 634 protein-altering or splice-affecting, 232 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 554, Silent 232, Nonsense Mutation 63, Intron 10, Splice Site 9, RNA 6, Frame Shift Del 4, 3'UTR 3, 5'UTR 3, Frame Shift Ins 2, Translation Start Site 1, Splice Region 1.

Variants (750 of 889; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYBB | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as rs137854588, CM910097, COSV66086104; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 40/140 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519924, COSV67962147; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55976286, COSV55980857; called by muse, mutect2, varscan2
- AASS | c.1938G>C p.L646F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62791383; called by muse, mutect2, varscan2
- ABCA3 | c.2399G>A p.R800K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773905661, COSV57052830, COSV57053313, COSV57058609; called by muse, mutect2, varscan2
- ABCA4 | c.6760G>T p.E2254* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV64676800; called by muse, mutect2, varscan2
- ABCC3 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV53316822; called by muse, mutect2, varscan2
- ABCC4 | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV65317239; called by muse, mutect2
- ABCC6 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs72653759, CM012884, CM080011, COSV52747059; called by muse, mutect2, varscan2
- ABCD4 | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100084326, COSV53991770; called by muse, mutect2, varscan2
- ABI1 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV61019131, COSV61019514; called by muse, mutect2, varscan2
- ACAD11 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1559952176, COSV99392115; called by muse, mutect2
- ACAP2 | c.1556C>A p.S519* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV58752006, COSV58754889; called by muse, mutect2
- ACP4 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54518422; called by muse, mutect2, varscan2
- ACR | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as rs139675699; called by muse, mutect2, varscan2
- ACSM2A | c.1492G>C p.D498H (on ENST00000219054; = p.D419H on NM_001308169.2) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54588564; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2843C>G p.S948* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV65897176; called by muse, mutect2, varscan2
- ADAR | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV52719787; called by muse, mutect2, varscan2
- ADGRG4 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54964484; called by muse, mutect2, varscan2
- ADGRL2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV54683771; called by muse, mutect2, varscan2
- ADIPOR2 | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs1289678782, COSV63947464; called by muse, mutect2, varscan2
- AGAP3 | c.505G>A p.E169K (on ENST00000622464; = p.E205K on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58995905; called by muse, mutect2, varscan2
- AGFG1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs755915101, COSV59514308; called by muse, mutect2, varscan2
- AGT | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760531325, COSV64185341; called by muse, mutect2, varscan2
- AGTPBP1 | c.3626C>T p.S1209F (on ENST00000357081 / NM_001330701.2; = p.S1169F on NM_015239.2) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.36); catalogued as COSV61274017; called by muse, mutect2, varscan2
- AK6 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as COSV66459373; called by muse, mutect2
- AKAP17A | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58311597; called by muse, mutect2
- ALG13 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV52643880; called by muse, mutect2
- ALMS1 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52519335; called by muse, mutect2, varscan2
- AMMECR1 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV53319787; called by muse, mutect2, varscan2
- AMOTL2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV99998190; called by muse, mutect2, varscan2
- ANAPC2 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100118954, COSV58808783; called by muse, mutect2, varscan2
- ANKAR | c.4164G>C p.K1388N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51462116, COSV51463534; called by muse, mutect2
- ANKRD12 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50841416; called by muse, mutect2, varscan2
- ANKRD36B | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as rs1398808941; called by muse, varscan2
- AP1S3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.807); catalogued as COSV57512564; called by muse, mutect2, varscan2
- AP2A2 | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs777993214, COSV59963402; called by muse, mutect2, varscan2
- AP4B1 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV56726367, COSV56726581; called by muse, mutect2, varscan2
- APBA2 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV68794434; called by muse, mutect2, varscan2
- APTX | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV58930237; called by muse, mutect2, varscan2
- AR | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV65962754; called by muse, mutect2
- ARFGEF1 | c.4939G>A p.E1647K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV51608213, COSV51615492; called by muse, mutect2, varscan2
- ARFGEF3 | c.2807C>T p.S936L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1451219615, COSV52468018; called by muse, mutect2, varscan2
- ARHGEF18 | c.2058C>G p.F686L (on ENST00000359920 / NM_001130955.2; = p.F582L on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100149574; called by muse, mutect2, varscan2
- ARMCX1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV65705458; called by muse, mutect2, varscan2
- ARSF | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63840759; called by muse, mutect2, varscan2
- ASPN | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65016072, COSV65016561; called by muse, mutect2, varscan2
- ASTN1 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62494603, COSV62503996; called by muse, mutect2, varscan2
- ASXL1 | c.2612C>G p.S871* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60118511; called by muse, mutect2, varscan2
- ATL1 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1269848425, COSV63297403; called by muse, mutect2, varscan2
- ATP13A2 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV58702974; called by muse, mutect2, varscan2
- ATP1B4 | c.1027G>A p.D343N (on ENST00000218008 / NM_001142447.3; = p.D339N on NM_012069.5) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54314478, COSV99486544; called by muse, mutect2, varscan2
- ATP5IF1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV55282827; called by muse, mutect2, varscan2
- ATXN2L | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1224532741, COSV57377379; called by muse, mutect2
- ATXN2L | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57377409; called by muse, mutect2, varscan2
- ATXN2L | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV57377441; called by muse, mutect2, varscan2
- ATXN3L | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV66076151; called by muse, mutect2, varscan2
- BACH2 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV57604472; called by muse, mutect2
- BAG6 | c.2255C>T p.S752F (on ENST00000676571; = p.S705F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52994159; called by muse, mutect2, varscan2
- BAHD1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs199651782; called by muse, mutect2
- BAZ1B | c.2455G>C p.D819H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV59993605; called by muse, mutect2, varscan2
- BAZ1B | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV59993615; called by muse, mutect2, varscan2
- BCKDK | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs553956491, COSV54893477; called by muse, mutect2
- BRWD3 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64746150; called by muse, mutect2, varscan2
- BTAF1 | c.4819C>G p.L1607V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV56438239; called by muse, mutect2, varscan2
- C12orf71 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70282852; called by muse, mutect2, varscan2
- C18orf25 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56368414; called by muse, mutect2, varscan2
- C1QTNF6 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV55397215; called by muse, mutect2, varscan2
- C1orf226 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs905068861, COSV63396508; called by muse, mutect2, varscan2
- C1orf87 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV64598383; called by muse, mutect2, varscan2
- C2CD6 | c.1566C>G p.F522L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53799392; called by muse, varscan2
- C6orf62 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV65290885; called by muse, mutect2, varscan2
- CACNA1S | c.4621G>C p.E1541Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62942776; called by muse, mutect2, varscan2
- CACNB2 | c.166G>A p.D56N (on ENST00000324631 / NM_201596.3; = p.D28N on NM_201571.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56642305; called by muse, varscan2
- CADM1 | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV59020410; called by muse, mutect2, varscan2
- CALCB | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60834368; called by muse, mutect2, varscan2
- CAMKK2 | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV61217155; called by muse, mutect2, varscan2
- CAMTA1 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV57921653; called by muse, mutect2, varscan2
- CASKIN2 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58599118; called by muse, mutect2, varscan2
- CATIP | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV56824118; called by muse, mutect2, varscan2
- CATSPERB | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV56432748; called by muse, mutect2, varscan2
- CAVIN2 | c.139A>T p.I47F | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV58425370; called by muse, mutect2, varscan2
- CCDC159 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs759504170, COSV52261880; called by muse, mutect2, varscan2
- CCDC66 | c.1264G>A p.E422K (on ENST00000394672 / NM_001353147.1; = p.E388K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV58308170; called by muse, mutect2, varscan2
- CCNF | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as COSV53542425; called by muse, mutect2, varscan2
- CCR3 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62465482; called by muse, mutect2, varscan2
- CD99L2 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV60938020; called by muse, mutect2, varscan2
- CDC20B | c.995C>G p.S332* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV57056212; called by muse, mutect2
- CDCA2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.043); catalogued as COSV57948071; called by muse, mutect2, varscan2
- CDH1 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.447); catalogued as COSV55739023; called by muse, mutect2, varscan2
- CDH13 | c.2045G>A p.C682Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51859852; called by muse, mutect2
- CDHR5 | c.2458G>A p.E820K (on ENST00000358353 / NM_001171968.2; = p.E826K on NM_021924.5) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs373271397; called by muse, mutect2
- CELSR1 | c.8719G>A p.D2907N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV53097729; called by muse, mutect2, varscan2
- CEP162 | c.2582G>C p.R861T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57623221; called by muse, mutect2, varscan2
- CHD8 | c.4648G>C p.D1550H (on ENST00000646647 / NM_001170629.2; = p.D1271H on NM_020920.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV63219535, COSV63219851; called by muse, mutect2, varscan2
- CHD8 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV67872281; called by muse, mutect2, varscan2
- CHRNA1 | c.1183G>A p.D395N (on ENST00000261007 / NM_001039523.3; = p.D370N on NM_000079.4) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); catalogued as COSV53684665; called by muse, mutect2, varscan2
- CIC | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.074); catalogued as COSV50650075; called by muse, mutect2, varscan2
- CLCN3 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100641728; called by muse, mutect2
- CLK2 | c.880G>A p.E294K (on ENST00000368361 / NM_001294339.2; = p.E293K on NM_003993.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56947027; called by muse, mutect2, varscan2
- CMTM2 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV51749504; called by muse, mutect2, varscan2
- CNKSR1 | c.1465G>A p.D489N (on ENST00000374253 / NM_001297647.2; = p.D482N on NM_006314.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV58794257; called by muse, mutect2, varscan2
- CNNM2 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1218026306, COSV100881797, COSV64001480; called by muse, mutect2, varscan2
- CNNM4 | c.2188C>G p.Q730E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV65661544, COSV65661919; called by muse, mutect2, varscan2
- CNTN4 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs905745699, COSV61879272; called by muse, mutect2, varscan2
- COL5A1 | c.2940G>C p.Q980H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65673532; called by muse, mutect2, varscan2
- COL6A5 | c.6106G>A p.D2036N (on ENST00000312481; = p.D2032N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778905248, COSV99593395; called by muse, varscan2
- COL6A6 | c.1952A>G p.K651R | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100650320; called by muse, mutect2, varscan2
- COL8A2 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.622); catalogued as COSV57443108; called by muse, mutect2, varscan2
- COL8A2 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57443116; called by mutect2, varscan2
- CPAMD8 | c.1867C>T p.Q623* (on ENST00000651564; = p.Q576* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV52234606; called by muse, mutect2, varscan2
- CRAMP1 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as COSV51965348; called by mutect2, varscan2
- CRB2 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV63505108; called by muse, mutect2, varscan2
- CROCC | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs779927599, COSV100978263; called by muse, mutect2, varscan2
- CROT | c.1707C>G p.I569M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58976366; called by muse, mutect2, varscan2
- CSMD1 | c.8455G>C p.E2819Q (on ENST00000520002; = p.E2818Q on NM_033225.6) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs922833777, COSV100144229, COSV59369563; called by muse, mutect2, varscan2
- CTSZ | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99413592; called by muse, mutect2
- CTTNBP2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV50456333; called by muse, mutect2, varscan2
- CUBN | c.2278G>A p.D760N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV64724648; called by muse, mutect2, varscan2
- CUL1 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as COSV57391663; called by muse, mutect2, varscan2
- CYHR1 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs200023926, COSV56762571; called by muse, mutect2, varscan2
- CYP2E1 | c.1387C>G p.L463V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.985); catalogued as COSV53314910; called by muse, mutect2, varscan2
- CYTH2 | c.970G>C p.E324Q (on ENST00000427476; = p.E323Q on NM_004228.7) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57310452; called by muse, mutect2, varscan2
- DAAM2 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.035); catalogued as rs933336879, COSV51412266; called by muse, mutect2, varscan2
- DAAM2 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs1046301441, COSV51412507; called by muse, mutect2, varscan2
- DBNDD1 | c.235G>A p.E79K (on ENST00000002501 / NM_001042610.3; = p.E99K on NM_024043.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50022557; called by muse, mutect2, varscan2
- DCUN1D4 | c.793G>T p.D265Y (on ENST00000334635 / NM_001287757.1; = p.D230Y on NM_015115.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745489867, COSV100584537, COSV58120434; called by muse, mutect2, varscan2
- DGAT2L6 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV100284115, COSV60718494; called by muse, mutect2, varscan2
- DHPS | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DHX29 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.057); catalogued as COSV52421224; called by muse, mutect2, varscan2
- DHX30 | c.2401G>C p.E801Q (on ENST00000445061 / NM_138615.3; = p.E762Q on NM_014966.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV53141600; called by muse, mutect2, varscan2
- DKK3 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV58869925; called by muse, mutect2, varscan2
- DNAH17 | c.12064G>C p.E4022Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67759858, COSV67762304; called by muse, mutect2, varscan2
- DNAJB7 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV53423365; called by muse, mutect2, varscan2
- DNAJC13 | c.3733C>G p.P1245A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53456223; called by muse, mutect2, varscan2
- DNAJC14 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV57912128, COSV57914044; called by muse, varscan2
- DOCK11 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.751); catalogued as COSV52245967; called by muse, mutect2
- DOP1B | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs1043078276, COSV67695409; called by muse, mutect2, varscan2
- DST | c.18571C>T p.L6191F (on ENST00000361203 / NM_001374722.1; = p.L3888F on NM_015548.5) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55034562; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.497A>C p.K166T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.208); catalogued as COSV99143668; called by muse, varscan2
- ECT2 | c.1304C>G p.S435C (on ENST00000392692 / NM_001349098.2; = p.S404C on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV51692917; called by muse, mutect2, varscan2
- EDEM2 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs755505781, COSV65713543; called by muse, mutect2
- EDN1 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV65081016; called by muse, mutect2, varscan2
- EHMT2 | c.3072G>C p.W1024C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57668815; called by muse, mutect2, varscan2
- EIF2AK3 | c.3040C>G p.L1014V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57551084; called by muse, mutect2
- EIF3L | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67739443; called by muse, mutect2, varscan2
- ELAPOR1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV64041056; called by muse, mutect2, varscan2
- EMP1 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.525); catalogued as COSV56999218; called by muse, varscan2
- EP400 | c.6991G>A p.E2331K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV57783568; called by muse, mutect2, varscan2
- EPHA2 | c.1843C>G p.R615G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV64454440; called by muse, mutect2, varscan2
- EPOR | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.454); catalogued as COSV55801252, COSV55801348; called by muse, mutect2, varscan2
- EPPK1 | c.6595G>A p.D2199N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.171); catalogued as rs781845353, COSV73262280; called by muse, mutect2, varscan2
- ERBIN | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52324770; called by muse, mutect2, varscan2
- ERICH6 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV55802613; called by muse, mutect2, varscan2
- ESS2 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52818427; called by muse, mutect2, varscan2
- EZH1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs867021719, COSV70550390; called by muse, mutect2, varscan2
- FABP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55559226; called by muse, mutect2, varscan2
- FADS1 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV63521013; called by muse, mutect2, varscan2
- FAM151A | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56365905; called by muse, mutect2, varscan2
- FAM151B | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56474861; called by muse, mutect2, varscan2
- FAM160A2 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.622); catalogued as COSV56414003; called by muse, mutect2, varscan2
- FAM180A | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.157); catalogued as COSV58528969; called by muse, mutect2, varscan2
- FAM184A | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as rs1416585893, COSV58857715; called by muse, mutect2, varscan2
- FAM217B | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV62564982; called by muse, mutect2, varscan2
- FAM222B | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.362); catalogued as COSV57933205; called by muse, mutect2, varscan2
- FAM91A1 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV58239074; called by muse, mutect2, varscan2
- FASN | c.5397C>G p.F1799L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60759859; called by muse, mutect2, varscan2
- FAT2 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV55815063; called by muse, mutect2, varscan2
- FAT2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV55827422; called by muse, mutect2, varscan2
- FAT3 | c.2650G>A p.G884R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53161051; called by muse, mutect2, varscan2
- FAT3 | c.6328G>T p.D2110Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53104553; called by muse, mutect2, varscan2
- FBXL4 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV57749065; called by muse, mutect2, varscan2
- FBXO24 | c.804G>T p.K268N (on ENST00000241071 / NM_033506.3; = p.K306N on NM_012172.5) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53826938; called by muse, mutect2, varscan2
- FCMR | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV65569229; called by muse, mutect2, varscan2
- FGF3 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143593259; called by muse, mutect2, varscan2
- FLG2 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV66171979, COSV66172265; called by muse, mutect2, varscan2
- FNBP1 | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63089745; called by muse, mutect2, varscan2
- FOXO4 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58576221; called by muse, mutect2, varscan2
- FOXRED2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV53401402; called by muse, mutect2, varscan2
- FRAS1 | c.8961G>A p.V2987= | Splice Region (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99352647; called by muse, varscan2
- FRAS1 | c.9217C>T p.Q3073* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV53625191; called by muse, mutect2, varscan2
- FREM2 | c.5723G>C p.G1908A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54848706; called by muse, mutect2, varscan2
- FRMD4B | c.806C>G p.P269R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV68332756; called by muse, mutect2, varscan2
- FRMD8 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100454717; called by muse, mutect2, varscan2
- FRMPD2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV59722461; called by muse, mutect2, varscan2
- FSCB | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.278); catalogued as COSV61218205; called by muse, mutect2, varscan2
- FYN | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV99991885; called by muse, mutect2
- FZD7 | c.1680C>G p.F560L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); catalogued as COSV53811301; called by muse, mutect2
- GABBR2 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52316285; called by muse, mutect2, varscan2
- GARRE1 | c.2357C>G p.S786C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as rs1475469255, COSV100209485; called by muse, mutect2
- GBP7 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV54011337; called by muse, mutect2, varscan2
- GDF5 | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.402); catalogued as COSV100976844, COSV65499254, COSV65501420; called by muse, mutect2
- GDF9 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs746785370, COSV51526979; called by muse, mutect2, varscan2
- GFPT2 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53811510; called by muse, varscan2
- GGCX | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as COSV52089991, COSV52090498; called by muse, varscan2
- GIGYF1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV51945882; called by muse, mutect2, varscan2
- GJA9 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62532657; called by muse, mutect2, varscan2
- GLI3 | c.2051C>T p.S684L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV67893827; called by muse, mutect2, varscan2
- GLIS3 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs202218708, COSV100174164; called by muse, varscan2
- GLUL | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV59383104; called by muse, mutect2, varscan2
- GOLGB1 | c.8476G>C p.D2826H | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV100510969; called by muse, mutect2, varscan2
- GOLGB1 | c.8317G>C p.E2773Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61469764; called by muse, mutect2, varscan2
- GOLGB1 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV61469772; called by muse, mutect2, varscan2
- GPKOW | c.457-1G>T p.X153_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV50244766; called by muse, mutect2, varscan2
- GPR107 | c.1729G>A p.E577K (on ENST00000372406 / NM_001136557.2; = p.E529K on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61282032; called by muse, mutect2, varscan2
- GRAMD1A | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1035459969, COSV58768631; called by muse, mutect2, varscan2
- GRIP1 | c.1975G>A p.D659N (on ENST00000359742 / NM_001379345.1; = p.D607N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as COSV54023424, COSV54038092; called by muse, mutect2, varscan2
- GRXCR1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV67671083, COSV67673987; called by muse, mutect2, varscan2
- GSDMC | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV52698328, COSV99415790; called by muse, mutect2, varscan2
- GSTA2 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV72414917; called by muse, mutect2, varscan2
- H3C3 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV63550652, COSV63551431, COSV63551470; called by mutect2, varscan2
- HCK | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV52943614, COSV99394205; called by muse, mutect2, varscan2
- HECTD4 | c.12044G>A p.G4015E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1383894732, COSV66397939; called by muse, mutect2, varscan2
- HECW2 | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV53671271; called by muse, mutect2, varscan2
- HERC6 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV52033676; called by muse, mutect2, varscan2
- HEXB | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs550315046, COSV54669491; called by muse, mutect2, varscan2
- HFM1 | c.2620G>C p.D874H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54026490, COSV54035128; called by muse, mutect2, varscan2
- HIP1 | c.2906C>G p.S969* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV61190392; called by muse, mutect2, varscan2
- HLA-A | c.1031-1G>C p.X344_splice (on ENST00000376806; = p.X338_splice on NM_002116.8) | Splice Site (SNP) | VAF 61/161 reads (38%) | catalogued as COSV65144691; called by muse, mutect2
- HLA-B | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 28/170 reads (16%) | catalogued as COSV69522776, COSV69523296; called by muse, varscan2
- HLA-E | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.991); catalogued as COSV100931909, COSV100931976, COSV64927856; called by muse, mutect2, varscan2
- HMMR | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62375315; called by muse, mutect2
- HOXA6 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV56074523; called by muse, mutect2, varscan2
- HPS5 | c.2707G>A p.E903K (on ENST00000349215 / NM_181507.2; = p.E789K on NM_007216.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV100752241, COSV61687900; called by muse, mutect2
- HRC | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV53258347; called by muse, mutect2, varscan2
- HSPA4 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59183387; called by muse, mutect2, varscan2
- HSPB11 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as COSV52041665; called by muse, mutect2, varscan2
- HSPG2 | c.3524G>A p.C1175Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65975943; called by muse, mutect2, varscan2
- HUWE1 | c.4534G>C p.E1512Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV99472614; called by muse, varscan2
- IDE | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56426484; called by muse, mutect2, varscan2
- IDI2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV52988831; called by muse, mutect2, varscan2
- IFI16 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs1275724770, COSV55538944; called by muse, mutect2
- IFT81 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV54365892; called by muse, mutect2, varscan2
- IGSF10 | c.6390G>A p.M2130I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56379811; called by muse, mutect2, varscan2
- IGSF9B | c.3488C>T p.T1163I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs776345696, COSV58071630; called by muse, mutect2, varscan2
- IL12B | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.517); catalogued as COSV51455792; called by muse, mutect2, varscan2
- IL17A | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV60683916, COSV60684793; called by muse, mutect2, varscan2
- IL27RA | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV54602595; called by muse, mutect2, varscan2
- INPP5E | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757592615, COSV65497040; called by muse, mutect2, varscan2
- INTS6L | c.2248G>C p.D750H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs527897696, COSV66085787; called by muse, mutect2, varscan2
- INVS | c.2396G>A p.R799K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV52448165; called by muse, mutect2
- IQCN | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs767219841, COSV66576906; called by muse, mutect2, varscan2
- IRF6 | c.1296C>G p.I432M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.201); catalogued as CD133967, COSV54214889, COSV54215255; called by muse, mutect2, varscan2
- ITGAD | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV66759688; called by muse, mutect2, varscan2
- JAK3 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as COSV71687192; called by muse, mutect2, varscan2
- JARID2 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as COSV59196099; called by muse, mutect2, varscan2
- JHY | c.1546C>G p.H516D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57079067; called by muse, mutect2, varscan2
- JMY | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV68662054; called by muse, mutect2, varscan2
- KCNIP3 | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371878238, COSV54671902; called by muse, mutect2, varscan2
- KCNK13 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56410841, COSV56416329; called by muse, mutect2, varscan2
- KDM4C | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1451894980, COSV67191072; called by muse, mutect2, varscan2
- KIAA0319L | c.1685C>G p.S562C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57849556; called by muse, mutect2, varscan2
- KIAA2026 | c.2877G>C p.E959D | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV67357093; called by muse, mutect2, varscan2
- KIF21A | c.3583A>T p.I1195F (on ENST00000361418 / NM_001378440.1; = p.I1182F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV62776662; called by muse, mutect2, varscan2
- KIF21A | c.3582G>C p.E1194D (on ENST00000361418 / NM_001378440.1; = p.E1181D on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV62776672; called by muse, mutect2, varscan2
- KIF6 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs537999500, COSV54690653, COSV99759736; called by muse, mutect2, varscan2
- KLHL4 | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV64146777, COSV64146831; called by muse, mutect2, varscan2
- KNTC1 | c.3531G>T p.M1177I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61083270; called by muse, mutect2
- KRBA1 | c.2624G>A p.W875* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as rs751823457, COSV55443703; called by muse, mutect2, varscan2
- KRT20 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754776993, COSV51425901; called by muse, mutect2, varscan2
- KRT32 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV56787754; called by muse, varscan2
- KRTAP10-4 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV59975696; called by muse, mutect2, varscan2
- LCOR | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs373519273, COSV53716416; called by mutect2, varscan2
- LEPR | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.404); catalogued as COSV60758343, COSV60762153; called by muse, mutect2, varscan2
- LGALS3BP | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53165819; called by muse, mutect2, varscan2
- LIMD1 | c.1862G>C p.R621T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56267342; called by muse, mutect2, varscan2
- LIPE | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); catalogued as COSV99734151; called by muse, mutect2
- LIPG | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54297706; called by muse, mutect2, varscan2
- LLGL2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1160573739, COSV51393068; called by muse, mutect2, varscan2
- LMCD1 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50091145; called by muse, mutect2, varscan2
- LRP2 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55553236; called by muse, mutect2, varscan2
- LRRC23 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as COSV50394597; called by muse, mutect2, varscan2
- LRRC25 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59115812; called by muse, mutect2, varscan2
- LRRC34 | c.754G>A p.E252K (on ENST00000446859 / NM_001172779.2; = p.E220K on NM_153353.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57187621; called by muse, mutect2
- LRRC41 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58441901; called by muse, mutect2, varscan2
- LRRC49 | c.627G>C p.R209S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.298); catalogued as COSV53014457; called by muse, mutect2, varscan2
- LRRC75B | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV50644024; called by muse, mutect2, varscan2
- LRTM2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs527284344, COSV54564410, COSV54564443, COSV99765395; called by muse, mutect2, varscan2
- LVRN | c.818T>A p.L273H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1017980642, COSV63498153; called by muse, mutect2, varscan2
- LYST | c.3925C>G p.L1309V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV67712257; called by muse, mutect2, varscan2
- MAGEC1 | c.1349C>G p.S450C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.869); catalogued as rs140353352, COSV53579558; called by muse, mutect2, varscan2
- MAGED1 | c.1145C>G p.T382S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV58516494; called by muse, mutect2, varscan2
- MAGED1 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV58516503; called by muse, mutect2, varscan2
- MAMDC2 | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV65860113, COSV65860628; called by muse, mutect2, varscan2
- MAN2B1 | c.1458C>G p.F486L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99667011; called by muse, mutect2, varscan2
- MAP1B | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57104660; called by muse, mutect2, varscan2
- MAP3K2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV61295794; called by muse, mutect2, varscan2
- MAP3K20 | c.773C>G p.S258* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV59105725; called by muse, mutect2, varscan2
- MAP3K5 | c.2742C>G p.F914L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62891498; called by muse, mutect2, varscan2
- MAP4K1 | c.2357G>A p.R786K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.122); catalogued as COSV67712833; called by muse, varscan2
- MAP4K1 | c.2155G>C p.D719H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67712551; called by muse, mutect2
- MAP7D3 | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60172194; called by muse, varscan2
- MAPK15 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV62029692; called by muse, mutect2, varscan2
- MAPK15 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1314484085, COSV62029712; called by muse, mutect2, varscan2
- MAST1 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV52253053; called by muse, mutect2
- MDC1 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV64526698; called by muse, mutect2
- MDH1 | c.799del p.V267Cfs*25 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as COSV51863389, COSV51864762; called by mutect2, pindel, varscan2
- MDN1 | c.16496G>A p.R5499Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466064330, COSV65519801; called by muse, mutect2
- MED1 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as rs749245401, COSV56125123; called by muse, mutect2, varscan2
- MED1 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56127878; called by muse, varscan2
- MED1 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100327864; called by muse, varscan2
- MED1 | c.1810C>G p.L604V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV56127886; called by muse, mutect2, varscan2
- MED1 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV56127896; called by muse, mutect2, varscan2
- MED14 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61358223; called by muse, mutect2, varscan2
- MEF2A | c.698C>T p.S233F (on ENST00000557942 / NM_001319206.2; = p.S235F on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57536604; called by muse, mutect2, varscan2
- MEI1 | c.2238C>G p.I746M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV55906468; called by muse, mutect2, varscan2
- MEPE | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV63074140; called by muse, mutect2
- MKRN2 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1399736875, COSV50107652; called by muse, mutect2, varscan2
- MMP1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as COSV100187986; called by muse, mutect2
- MMP19 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59452794; called by muse, mutect2, varscan2
- MMP2 | c.1345C>G p.P449A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54604482; called by muse, mutect2, varscan2
- MOB3C | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54719099, COSV54720283; called by muse, mutect2, varscan2
- MOCS1 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs111379764; called by muse, mutect2, varscan2
- MORC1 | c.1552C>A p.R518S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as rs115832406, COSV51726976; called by muse, mutect2, varscan2
- MTNR1B | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138675484, COSV57065563; called by muse, mutect2, varscan2
- MUC16 | c.11336C>T p.S3779F | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs772201780, COSV101200307, COSV67486924, COSV67486990; called by muse, mutect2, varscan2
- MXRA5 | c.4148C>G p.S1383* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54233684, COSV54246466; called by muse, mutect2, varscan2
- MYH9 | c.3448G>T p.D1150Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53391714; called by muse, mutect2, varscan2
- MYH9 | c.3273-1G>A p.X1091_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV53391723, COSV53395378; called by mutect2, varscan2
- MYH9 | c.2932G>C p.E978Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV53391732; called by muse, mutect2, varscan2
- MYH9 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV53391752; called by muse, mutect2, varscan2
- MYO10 | c.2070G>C p.M690I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV57028407; called by muse, mutect2, varscan2
- MYO1F | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV57799170; called by muse, mutect2, varscan2
- NAA50 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs976689805, COSV53787054; called by muse, mutect2, varscan2
- NADK | c.341G>C p.R114T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.405); catalogued as COSV58275911; called by muse, mutect2
- NAF1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as COSV56805668; called by muse, mutect2, varscan2
- NAGLU | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as CD023526, COSV56795407, COSV56795987; called by muse, mutect2, varscan2
- NAGS | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.229); catalogued as COSV53228198; called by muse, mutect2, varscan2
- NAIP | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52002525; called by muse, mutect2, varscan2
- NAPB | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV65463995; called by muse, mutect2, varscan2
- NAPB | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65465116; called by muse, mutect2, varscan2
- NAT9 | c.468C>A p.F156L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52854651; called by muse, mutect2, varscan2
- NAV1 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs753354868, COSV55224145; called by muse, mutect2, varscan2
- NAV3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57105569; called by muse, mutect2
- NBAS | c.2920C>T p.Q974* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV55724569; called by muse, mutect2, varscan2
- NBEAL1 | c.4283C>G p.S1428C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV71375260; called by muse, mutect2, varscan2
- NCAN | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.533); catalogued as COSV53055929; called by muse, mutect2, varscan2
- NCOA6 | c.1707G>C p.Q569H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV62867012; called by muse, mutect2, varscan2
- NDC80 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV55249403; called by muse, mutect2, varscan2
- NEB | c.13069G>C p.D4357H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51450582; called by muse, mutect2
- NEK4 | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV51782656; called by muse, mutect2, varscan2
- NELL2 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1197781747, COSV61568549, COSV61583526; called by muse, mutect2, varscan2
- NEMF | c.2781G>C p.Q927H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV53594521; called by muse, mutect2, varscan2
- NEMF | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.147); catalogued as COSV53594530; called by muse, varscan2
- NEUROD4 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV54473677; called by muse, mutect2, varscan2
- NHS | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101196751, COSV66280789; called by muse, mutect2, varscan2
- NIM1K | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534141752, COSV58143849; called by muse, mutect2
- NLRP2 | c.2224G>C p.D742H | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs774007013, COSV54759248; called by muse, mutect2, varscan2
- NME8 | c.1029C>A p.F343L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52254494; called by muse, mutect2, varscan2
- NME9 | c.256C>G p.L86V (on ENST00000333911 / NM_001349024.2; = p.L64V on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs940257205, COSV58619224, COSV58621943; called by muse, mutect2
- NOD2 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.148); catalogued as COSV56054103; called by muse, mutect2, varscan2
- NODAL | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV54662357, COSV54662626; called by muse, mutect2, varscan2
- NOL12 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV63031575; called by muse, mutect2, varscan2
- NOL8 | c.2416G>C p.E806Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62635333, COSV62637227; called by muse, mutect2, varscan2
- NPC1L1 | c.3614C>T p.S1205F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56929359; called by muse, mutect2
- NR3C1 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.78); PolyPhen probably damaging (0.986); catalogued as rs756635644, COSV99196349; called by mutect2, varscan2
- NR3C1 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51546030; called by muse, mutect2, varscan2
- NR5A2 | c.238G>A p.E80K (on ENST00000367362 / NM_205860.3; = p.E34K on NM_003822.5) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.104); catalogued as COSV52653045; called by muse, mutect2, varscan2
- NRG2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV99180381; called by muse, mutect2, varscan2
- NT5C | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as rs146917283, COSV55461888; called by muse, mutect2, varscan2
- NT5C1A | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52496010; called by muse, mutect2, varscan2
- NTN4 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs193920922, COSV59222574; ClinVar: uncertain significance; called by muse, varscan2
- NUP155 | c.3433G>C p.E1145Q (on ENST00000231498 / NM_153485.3; = p.E1086Q on NM_004298.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51533619; called by muse, mutect2, varscan2
- NUP160 | c.3267C>G p.I1089M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV65855614; called by muse, mutect2, varscan2
- NUP210L | c.1663C>T p.H555Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV55155486; called by muse, mutect2, varscan2
- NUP214 | c.3384G>C p.L1128F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV63912372; called by muse, mutect2, varscan2
- NUP58 | c.21C>A p.F7L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); catalogued as COSV67751000, COSV67751957; called by muse, mutect2, varscan2
- NUP98 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as rs1250679067, COSV61437431; called by muse, mutect2, varscan2
- NWD1 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as rs1468048892, COSV60349468; called by muse, mutect2, varscan2
- OAS3 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57448401; called by muse, mutect2, varscan2
- OCA2 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62355627; called by muse, mutect2
- OR10G7 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57865600, COSV57868499; called by muse, mutect2, varscan2
- OR10J3 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs776828671, COSV59954310, COSV59955418; called by muse, mutect2, varscan2
- OR13C2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV73377777; called by muse, mutect2, varscan2
- OR2W3 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV64456416, COSV64457796; called by muse, mutect2, varscan2
- OR4B1 | c.547T>C p.F183L | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.168); catalogued as rs1190818537, COSV58883713; called by muse, mutect2, varscan2
- OR4M1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60063054; called by muse, mutect2, varscan2
- OR5H15 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62947779; called by muse, mutect2, varscan2
- OR5R1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56573362; called by muse, mutect2
- OSBP2 | c.1145G>T p.S382I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV60247459; called by muse, mutect2, varscan2
- OSBPL11 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV56175951; called by muse, mutect2, varscan2
- OSBPL9 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.053); catalogued as COSV100543494; called by muse, mutect2, varscan2
- PACS1 | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100270138; called by muse, mutect2, varscan2
- PACS1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as rs753938016, COSV57696314; called by muse, mutect2, varscan2
- PADI4 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV64923244; called by muse, varscan2
- PADI4 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV64924850; called by muse, varscan2
- PALMD | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV54166288; called by muse, mutect2, varscan2
- PAN2 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as rs1261616873, COSV57755550; called by muse, mutect2, varscan2
- PARD3 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs1234358017, COSV60749222; called by muse, mutect2, varscan2
- PCDHA8 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.321); catalogued as rs782725221, COSV100970716, COSV65336294; called by muse, mutect2, varscan2
- PCDHB11 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.26); catalogued as COSV53382672; called by muse, mutect2, varscan2
- PCDHGA7 | c.267G>C p.R89S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV104389870, COSV54012019; called by muse, mutect2, varscan2
- PCDHGB1 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV54012006; called by muse, mutect2, varscan2
- PCNT | c.9519G>A p.M3173I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs748060594, COSV64032027; called by muse, mutect2, varscan2
- PEAR1 | c.3026C>G p.S1009* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV52775282; called by muse, mutect2, varscan2
- PEX5L | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55854520, COSV55855050; called by muse, mutect2, varscan2
- PIK3R1 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.162); catalogued as COSV57136981; called by muse, mutect2, varscan2
- PIK3R3 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV53110478, COSV99422216; called by muse, mutect2, varscan2
- PIKFYVE | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV52247519; called by muse, mutect2, varscan2
- PIP5K1B | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.145); catalogued as COSV55255916; called by muse, mutect2, varscan2
- PKHD1 | c.9018C>A p.F3006L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.06); catalogued as COSV61890795; called by muse, mutect2, varscan2
- PLA2G4A | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs373613129; called by muse, mutect2, varscan2
- PLCB1 | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as rs1231287777, COSV62064376; called by muse, mutect2
- PLEC | c.10204G>C p.E3402Q (on ENST00000322810 / NM_201380.4; = p.E3292Q on NM_000445.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); catalogued as COSV59682010; called by muse, mutect2, varscan2
- PLEC | c.7903G>T p.E2635* (on ENST00000322810 / NM_201380.4; = p.E2525* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV59682057; called by muse, mutect2, varscan2
- PLEC | c.7054G>C p.E2352Q (on ENST00000322810 / NM_201380.4; = p.E2242Q on NM_000445.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.311); catalogued as COSV59682113; called by muse, mutect2
- PLEKHA1 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs758438533, COSV64570150; called by muse, mutect2, varscan2
- PLXNB1 | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56493333; called by muse, mutect2, varscan2
- PMFBP1 | c.2434G>C p.E812Q (on ENST00000537465; = p.E807Q on NM_031293.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751519942, COSV52830394; called by muse, mutect2, varscan2
- PMP22 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56603223; called by muse, mutect2, varscan2
- PMPCA | c.546G>C p.E182D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV65510708; called by muse, mutect2
- PNN | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs1169955754, COSV53768050; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157032854, COSV57967915; called by muse, mutect2, varscan2
- PODN | c.1285C>T p.R429C (on ENST00000395871; = p.R381C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs188732079, COSV100439626; called by muse, mutect2, varscan2
- POMT1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57646198; called by muse, mutect2, varscan2
- PPFIA1 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99557503; called by muse, mutect2, varscan2
- PPID | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV56988989; called by muse, mutect2, varscan2
- PPP1R10 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV64740234; called by muse, varscan2
- PPP1R10 | c.249G>C p.K83N | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV64740242; called by muse, mutect2, varscan2
- PPP1R12A | c.2233G>C p.E745Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.614); catalogued as COSV54112985; called by muse, mutect2, varscan2
- PPP1R3A | c.3184C>G p.Q1062E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52890895; called by muse, mutect2
- PPP1R3A | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV52890918, COSV99494298; called by muse, mutect2, varscan2
- PPP1R9A | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1032144563, COSV56907000; called by muse, mutect2, varscan2
- PPP2R2A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs1320034240, COSV60098562; called by muse, mutect2, varscan2
- PRDM4 | c.2094-1G>C p.X698_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57307163; called by muse, mutect2
- PREX2 | c.2024G>A p.R675K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761696818, COSV55794881; called by muse, mutect2, varscan2
- PRKAA2 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); catalogued as rs985601596, COSV64806013; called by muse, mutect2
- PRKCE | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV60327295; called by muse, mutect2, varscan2
- PRKCZ | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs901650050, COSV61598942; called by muse, mutect2, varscan2
- PRKD3 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); catalogued as COSV52217051; called by muse, mutect2, varscan2
- PRKDC | c.10705C>G p.Q3569E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58043306; called by muse, mutect2, varscan2
- PRRC2A | c.5387C>G p.S1796* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52994148; called by muse, mutect2, varscan2
- PRSS58 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV73488807; called by muse, mutect2, varscan2
- PTCHD1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV65062347; called by muse, mutect2, varscan2
- PUM2 | c.2368G>C p.D790H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV57584446; called by muse, mutect2, varscan2
- PWWP2A | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61047611; called by muse, mutect2, varscan2
- RAB1B | c.87+1G>A p.X29_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57583917; called by muse, mutect2, varscan2
- RAB1B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57582009; called by muse, mutect2, varscan2
- RAB8A | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV56292976; called by muse, mutect2, varscan2
- RALGPS2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61339315, COSV99056452; called by muse, mutect2, varscan2
- RANBP6 | c.2461G>C p.V821L | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52391023; called by muse, mutect2, varscan2
- RASA4 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV53551186; called by muse, mutect2
- RASAL2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs144830827, COSV62718499; called by muse, mutect2, varscan2
- RECQL | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); catalogued as rs766866319, COSV59085613; called by muse, mutect2, varscan2
- REEP2 | c.339G>C p.K113N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV54735751; called by muse, mutect2, varscan2
- RFC3 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66296926; called by muse, mutect2, varscan2
- RGS9 | c.1236C>G p.I412M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.865); catalogued as COSV52228593; called by muse, mutect2, varscan2
- RILPL1 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61553556; called by mutect2, varscan2
- RLN1 | c.270C>G p.F90L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV56346410, COSV56346885; called by muse, mutect2, varscan2
- RLN3 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54602583; called by muse, varscan2
- RNF10 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.031); catalogued as COSV58047590; called by muse, mutect2, varscan2
- RNF125 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV54186508; called by muse, mutect2, varscan2
- RNF41 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1474229603, COSV61504898; called by muse, mutect2, varscan2
- RNPEPL1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54373703; called by muse, mutect2, varscan2
- RPAP3 | c.1779G>C p.Q593H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV50042695; called by muse, mutect2
- RPGR | c.2773C>T p.L925F (on ENST00000339363 / NM_001367249.1; = p.L720F on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV58839082; called by muse, mutect2, varscan2
- RPGR | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58837635; called by muse, mutect2, varscan2
- RYR2 | c.4666G>C p.E1556Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63675178; called by muse, mutect2, varscan2
- RYR3 | c.10521C>A p.F3507L (on ENST00000389232; = p.F3508L on NM_001036.6) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV66805110; called by muse, mutect2, varscan2
- SAP130 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52095710, COSV52101399; called by muse, mutect2, varscan2
- SBF1 | c.4638C>G p.F1546L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62369984; called by muse, mutect2, varscan2
- SBNO2 | c.2805C>G p.F935L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62322883; called by muse, mutect2, varscan2
- SCNN1D | c.1330C>G p.R444G (on ENST00000338555; = p.R608G on NM_001130413.4) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs756980992, COSV57643944; called by muse, mutect2, varscan2
- SCPEP1 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV51855327; called by muse, mutect2, varscan2
- SCUBE2 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs908441787, COSV58543964; called by muse, mutect2, varscan2
- SDR16C5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58127965; called by muse, mutect2, varscan2
- SEMA3F | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV50034092; called by muse, mutect2
- SEMA6C | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as rs756069979, COSV59006703; called by muse, mutect2, varscan2
- SEPTIN7 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV63256506; called by muse, mutect2, varscan2
- SF1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57111668; called by muse, mutect2, varscan2
- SF3B3 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV56787093, COSV56790429; called by muse, mutect2, varscan2
- SF3B4 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54966618; called by muse, varscan2
- SF3B4 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV54966626; called by muse, varscan2
- SFI1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66292510; called by muse, mutect2, varscan2
- SH3TC2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV60466920; called by muse, mutect2
- SHROOM4 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs373712390, COSV56789829; called by muse, mutect2, varscan2
- SIRT1 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53018743, COSV53019906, COSV99281630; called by muse, mutect2, varscan2
- SIX5 | c.2104G>T p.E702* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV52181495, COSV52182384, COSV52183638; called by muse, mutect2, varscan2
- SIX5 | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52181503; called by muse, mutect2, varscan2
- SIX5 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs930806559, COSV52181508; called by muse, mutect2, varscan2
- SLC12A2 | c.2374C>T p.L792F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52475234; called by muse, mutect2, varscan2
- SLC19A2 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52548710; called by muse, mutect2, varscan2
- SLC22A14 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56198998, COSV56199656; called by muse, mutect2, varscan2
- SLC25A5 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV58629506; called by muse, varscan2
- SLC35G5 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55314776; called by muse, mutect2, varscan2
- SLC38A10 | c.2955G>A p.M985I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs765141868, COSV66103083; called by muse, mutect2, varscan2
- SLC38A10 | c.1029G>C p.E343D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55848426, COSV55849088; called by muse, mutect2, varscan2
- SLC6A1 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV55118221; called by muse, mutect2
- SLX4 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99568090; called by muse, mutect2, varscan2
- SMAD5 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV72597598; called by muse, mutect2, varscan2
- SMARCD2 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV56741381; called by muse, mutect2, varscan2
- SMC1A | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | catalogued as COSV59131390; called by muse, mutect2, varscan2
- SMG1 | c.10345G>A p.E3449K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV67174267; called by muse, mutect2, varscan2
- SMG1 | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 33/159 reads (21%) | catalogued as COSV67174275; called by muse, mutect2, varscan2
- SMG5 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62437259, COSV62437631; called by muse, mutect2, varscan2
- SMPD4 | c.2329C>G p.R777G (on ENST00000409031 / NM_017951.4; = p.R748G on NM_017751.4) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100302120, COSV60082262; called by muse, mutect2, varscan2
- SND1 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV61241273; called by muse, mutect2, varscan2
- SNED1 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV60031640; called by muse, mutect2, varscan2
- SNX25 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53017721; called by muse, mutect2, varscan2
- SNX5 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV66698463; called by muse, mutect2, varscan2
- SOCS5 | c.573G>C p.M191I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757917355, COSV60606107; called by mutect2, varscan2
- SP140 | c.977-1G>A p.X326_splice | Splice Site (SNP) | VAF 21/103 reads (20%) | catalogued as COSV59454021; called by muse, mutect2, varscan2
- SPAG17 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.624); catalogued as COSV60466086; called by muse, mutect2, varscan2
- SPAG5 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.442); catalogued as COSV58803831; called by muse, mutect2, varscan2
- SPAG8 | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV52415486; called by muse, mutect2, varscan2
- SPARCL1 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as COSV56803448, COSV56805791; called by muse, mutect2, varscan2
- SPATA1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV55364400; called by muse, mutect2, varscan2
- SPDL1 | c.997C>G p.L333V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774516530, COSV54669363; called by muse, mutect2
- SPTBN2 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474518395, COSV59447446, COSV59448261; called by muse, mutect2, varscan2
- SRBD1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55404197; called by muse, mutect2, varscan2
- SRCAP | c.7406C>A p.S2469* | Nonsense Mutation (SNP) | VAF 46/196 reads (23%) | catalogued as COSV52671366, COSV52679166; called by muse, varscan2
- SRCAP | c.7462C>G p.P2488A | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV52679177; called by muse, varscan2
- SRP68 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV57164322; called by muse, mutect2, varscan2
- SRRT | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV61454193; called by muse, mutect2, varscan2
- SRRT | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV53820671; called by muse, mutect2, varscan2
- SRRT | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53816098; called by muse, mutect2, varscan2
- SRSF9 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV57585385; called by muse, mutect2, varscan2
- ST6GAL1 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV51473188, COSV51473725; called by muse, mutect2
- STARD8 | c.2199G>C p.K733N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52931327; called by muse, mutect2, varscan2
- STAT6 | c.2006C>G p.S669C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV55667560; called by muse, mutect2, varscan2
- STAT6 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs749244007, COSV55667563; called by muse, mutect2, varscan2
- STPG2 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1315863946, COSV54816035; called by muse, mutect2, varscan2
- STYXL1 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50388148; called by muse, mutect2, varscan2
- SUMO1 | c.26C>G p.S9* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV66260798; called by muse, mutect2, varscan2
- SUPT7L | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV61823452; called by muse, mutect2, varscan2
- SYCP2 | c.3094G>C p.E1032Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62771620; called by muse, mutect2, varscan2
- SYN1 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV51694851; called by muse, mutect2, varscan2
- SYT9 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs779476138, COSV59616249; called by muse, mutect2
- TAAR1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51589215; called by muse, mutect2, varscan2
- TAB3 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55840052; called by muse, mutect2, varscan2
- TATDN2 | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); catalogued as COSV55053656; called by muse, mutect2, varscan2
- TCF20 | c.5509G>A p.E1837K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV59495112; called by muse, mutect2, varscan2
- TDRD6 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as COSV60177876; called by muse, mutect2, varscan2
- TEAD1 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV57569848; called by muse, mutect2, varscan2
- TENM2 | c.7279C>G p.Q2427E (on ENST00000518659 / NM_001122679.2; = p.Q2188E on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1200326933, COSV69138819; called by muse, mutect2, varscan2
- TERF1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs1360851634, COSV52579512; called by muse, mutect2, varscan2
- TERF1 | c.1167G>C p.K389N (on ENST00000276603 / NM_017489.3; = p.K369N on NM_003218.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as COSV52579523; called by muse, mutect2, varscan2
- TFAP2D | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.899); catalogued as COSV50417430; called by muse, mutect2, varscan2
- TFEC | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); catalogued as COSV55405944; called by muse, mutect2, varscan2
- THAP9 | c.1942C>G p.Q648E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs372184236; called by muse, mutect2, varscan2
- THOC3 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV54198474; called by muse, mutect2, varscan2
- THUMPD3 | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as COSV61506661; called by muse, varscan2
- TJP1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.4); catalogued as COSV62045372; called by muse, mutect2, varscan2
- TLE2 | c.261C>G p.I87M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758323007, COSV53582593, COSV99504461; called by mutect2, varscan2
- TLE6 | c.542-1G>A p.X181_splice (on ENST00000246112 / NM_001143986.2; = p.X58_splice on NM_024760.3) | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV55737284; called by muse, mutect2, varscan2
- TLR5 | c.669C>G p.F223L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.193); catalogued as COSV60560388; called by muse, mutect2, varscan2
- TLR5 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60560396; called by muse, mutect2, varscan2
- TM6SF2 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV66985714; called by muse, mutect2, varscan2
- TMEM101 | c.726G>C p.E242D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.08); catalogued as COSV52814027; called by muse, mutect2, varscan2
- TMEM108 | c.1230G>A p.M410I | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV58881797; called by muse, mutect2
- TMEM132B | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751942292, COSV54747583; called by muse, mutect2, varscan2
- TMEM145 | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV52098082; called by muse, mutect2, varscan2
- TMEM214 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53192385, COSV53193737; called by muse, mutect2, varscan2
- TMEM92 | c.477C>G p.F159L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV55946771; called by muse, varscan2
- TNFRSF11B | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV52073504; called by muse, mutect2, varscan2
- TNFRSF13B | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.175); catalogued as COSV55429918, COSV55430090; called by muse, mutect2, varscan2
- TRA2A | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV51718549; called by muse, mutect2, varscan2
- TRBV4-1 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs770183269; called by muse, mutect2, varscan2
- TRIM52 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV59844766; called by muse, mutect2, varscan2
- TRPC4 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV59013708; called by muse, mutect2, varscan2
- TRPM1 | c.3719C>G p.S1240C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV56640415; called by muse, mutect2, varscan2
- TRPM8 | c.1765C>G p.L589V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.112); catalogued as COSV61223704; called by muse, mutect2
- TRRAP | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100722554; called by muse, mutect2, varscan2
- TSC22D4 | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV55725136; called by muse, mutect2, varscan2
- TSPAN4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs766986570, COSV60260238; called by muse, mutect2, varscan2
- TTBK1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1398796119, COSV52494130; called by muse, mutect2, varscan2
- TTLL11 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV58651704; called by muse, mutect2, varscan2
- TTN | c.90925G>C p.E30309Q (on ENST00000591111; = p.E22885Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | PolyPhen probably damaging (0.997); catalogued as COSV60279236; called by muse, mutect2, varscan2
- TTN | c.84247G>T p.E28083* (on ENST00000591111; = p.E20659* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV60279260; called by muse, mutect2, varscan2
- TTN | c.62332G>C p.E20778Q (on ENST00000591111; = p.E13354Q on NM_003319.4) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | PolyPhen possibly damaging (0.698); catalogued as rs1460379508, COSV60108534, COSV60279276; called by muse, mutect2
- TTN | c.18646G>A p.E6216K (on ENST00000591111; = p.E5289K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | PolyPhen possibly damaging (0.736); catalogued as rs886042142, COSV60185601, COSV60279328; ClinVar: uncertain significance; called by muse, mutect2
- TUBGCP6 | c.4852G>A p.E1618K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs756859244, COSV50571843, COSV50573355; called by muse, mutect2, varscan2
- TXK | c.1439C>G p.S480C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51918900; called by muse, mutect2, varscan2
- TXNDC16 | c.1930C>G p.Q644E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1294168961, COSV55986781; called by muse, mutect2, varscan2
- UBR4 | c.11911G>A p.E3971K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100922105, COSV64396769; called by muse, mutect2, varscan2
- UBR5 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs780581220, COSV55296929; called by muse, mutect2, varscan2
- UBXN4 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as COSV55637329; called by muse, mutect2, varscan2
- UGT2A1 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54145627; called by muse, mutect2, varscan2
- UNC79 | c.3403G>C p.D1135H (on ENST00000393151 / NM_001346218.2; = p.D958H on NM_020818.5) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56405663; called by muse, mutect2, varscan2
- UNC80 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV55896681, COSV55902842; called by muse, mutect2, varscan2
- USP26 | c.2348C>G p.S783C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as COSV63709559; called by muse, mutect2, varscan2
- USP37 | c.2300-1G>T p.X767_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV51446600; called by muse, mutect2, varscan2
- USP48 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV57613540; called by muse, mutect2, varscan2
- VAMP5 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV60498422, COSV60499154; called by muse, mutect2
- VARS1 | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV63305032; called by muse, mutect2, varscan2
- VPS13D | c.4924C>T p.L1642F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV50669709; called by muse, mutect2, varscan2
- VPS13D | c.12733G>C p.E4245Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.087); catalogued as COSV50669792; called by muse, mutect2, varscan2
- VPS37D | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61446897; called by muse, mutect2, varscan2
- WDR24 | c.631G>C p.D211H (on ENST00000248142; = p.D149H on NM_032259.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50202608; called by muse, mutect2, varscan2
- WDR33 | c.3836C>G p.S1279C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV59254543; called by muse, mutect2, varscan2
- WDR36 | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV72411432; called by muse, mutect2, varscan2
- WDR47 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.136); catalogued as COSV63059354; called by muse, mutect2, varscan2
- WDR93 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51534665; called by muse, mutect2, varscan2
- WNK3 | c.3997C>T p.Q1333* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV63615520; called by muse, mutect2, varscan2
- XK | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66120722; called by muse, mutect2, varscan2
- XKR7 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143869401, COSV73813040; called by muse, mutect2, varscan2
- YIPF3 | c.289-1G>A p.X97_splice | Splice Site (SNP) | VAF 30/98 reads (31%) | catalogued as COSV58306723; called by muse, mutect2, varscan2
- YTHDC1 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.243); catalogued as COSV60011719; called by muse, mutect2
- ZBBX | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56797295, COSV56798487; called by muse, mutect2, varscan2
- ZBED9 | c.2942C>G p.S981C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1450571512, COSV71729712; called by muse, mutect2, varscan2
- ZBTB17 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV65271436; called by muse, mutect2, varscan2
- ZBTB40 | c.755C>G p.S252* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65145148; called by muse, mutect2, varscan2
- ZFHX4 | c.8368G>A p.E2790K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV51455498; called by muse, mutect2, varscan2
- ZFHX4 | c.10123G>T p.E3375* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV51489223; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as COSV66023930; called by muse, mutect2
- ZNF234 | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV70604038; called by muse, mutect2, varscan2
- ZNF275 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.139); catalogued as COSV100936305, COSV64703961; called by muse, varscan2
- ZNF275 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1176344484, COSV64704510, COSV64705210; called by muse, varscan2
- ZNF335 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as rs1338219991, COSV59819563; called by muse, mutect2, varscan2
- ZNF354C | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59609504; called by muse, mutect2, varscan2
- ZNF415 | c.1106C>G p.S369* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV54704199; called by mutect2, varscan2
- ZNF419 | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769964809, COSV55662370; called by muse, mutect2, varscan2
- ZNF467 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57374495; called by muse, mutect2, varscan2
- ZNF480 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57997836; called by muse, mutect2, varscan2
- ZNF512 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.525); catalogued as COSV62677722; called by muse, mutect2, varscan2
- ZNF574 | c.1858C>T p.R620W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55906340; called by muse, mutect2, varscan2
- ZNF618 | c.2491G>A p.E831K (on ENST00000374126 / NM_001318042.2; = p.E738K on NM_133374.2) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV55927652; called by muse, mutect2, varscan2
- ZNF638 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52494575; called by muse, mutect2, varscan2
- ZNF664 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61878579; called by muse, mutect2
- ZNF676 | c.590G>C p.R197T (on ENST00000650058; = p.R165T on NM_001001411.3) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV68094598; called by muse, mutect2, varscan2
- ZNF782 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100001630, COSV56654489; called by muse, mutect2, varscan2
- ZNF785 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV67876541; called by muse, mutect2, varscan2
- ZNF785 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV67876272, COSV67876546; called by muse, mutect2, varscan2
- ZNF808 | c.361del p.E121Kfs*12 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | catalogued as COSV63120068; called by pindel, varscan2
- ZNFX1 | c.2885G>C p.R962T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65578358; called by muse, mutect2, varscan2
- AP001781.2 | c.188dup p.G64Rfs*12 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2*
- DPPA4 | c.157del p.M53Cfs*41 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- FAT1 | c.279_280del p.F93Lfs*16 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, varscan2
- HNF1B | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); called by muse, mutect2
- IGLV1-51 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARPBP | c.648dup p.Q217Tfs*13 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.1149C>G p.N383K | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TBC1D3B | c.312G>C p.M104I | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ZNF488 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC10 | c.2247C>T p.L749= (on ENST00000372530 / NM_001198934.2; = p.L721= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs763453216, COSV55087618; called by muse, mutect2, varscan2
- ABCC6 | c.1326C>G p.V442= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1229396633, COSV52747054; called by muse, mutect2
- ABHD3 | c.195C>T p.F65= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV56678016; called by muse, mutect2, varscan2
- ACOX2 | c.2045G>A p.*682= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV57148158, COSV57150444; called by muse, mutect2, varscan2
- ACTR6 | c.390C>G p.L130= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV51842947; called by muse, mutect2, varscan2
- ADGRG3 | c.486C>T p.L162= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs774240704, COSV59650964; called by muse, mutect2, varscan2
- ADGRL1 | c.3306G>A p.K1102= (on ENST00000340736 / NM_001008701.3; = p.K1097= on NM_014921.5) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV61565709, COSV61565992; called by muse, mutect2, varscan2
- AFTPH | c.2301G>A p.L767= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs761251425, COSV53221079; called by muse, mutect2, varscan2
- AKR1B15 | c.390G>A p.L130= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs750762069, COSV71151535, COSV71152658; called by muse, mutect2, varscan2
- ALPK3 | c.249C>T p.L83= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV51938549; called by muse, mutect2, varscan2
- AMER1 | c.297G>A p.L99= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV57656858, COSV57665990; called by mutect2, varscan2
- ANKFN1 | c.1482G>C p.L494= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100593889, COSV59457227; called by muse, mutect2, varscan2
- ANKRD12 | c.3945C>T p.V1315= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV50841357; called by muse, mutect2, varscan2
- ANO1 | c.2505C>G p.L835= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV62448947; called by muse, mutect2, varscan2
- AP3D1 | c.3114C>T p.F1038= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100642735; called by muse, mutect2, varscan2
- ARHGEF28 | c.1821C>T p.I607= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV55250459; called by muse, mutect2, varscan2
- ARRB1 | c.312C>G p.L104= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV63577200; called by muse, mutect2, varscan2
- ASB17 | c.348G>A p.K116= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV52411721; called by muse, mutect2, varscan2
- ASXL2 | c.273G>A p.V91= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV55466062; called by muse, mutect2, varscan2
- ATF7IP2 | c.1782G>A p.L594= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV61095020; called by muse, mutect2, varscan2
- ATP10B | c.108G>C p.G36= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV58780726; called by muse, mutect2, varscan2
- ATP13A2 | c.1033C>T p.L345= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100454184; called by muse, mutect2, varscan2
- B3GNT8 | c.669C>G p.L223= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs953447281, COSV54199269; called by muse, mutect2, varscan2
- BICDL1 | c.1530G>A p.L510= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57492902, COSV99985845; called by muse, mutect2, varscan2
- BTBD11 | c.1419C>T p.F473= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV55034522, COSV99775308; called by muse, mutect2, varscan2
- BTN2A1 | c.1065C>T p.F355= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs767714942, COSV57005797; called by muse, mutect2, varscan2
- C2CD3 | c.5670G>A p.L1890= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58098785; called by muse, mutect2
- C5AR2 | c.873C>T p.F291= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1038541607, COSV57257083; called by muse, mutect2, varscan2
- CACNA1B | c.3750G>C p.L1250= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53143408; called by muse, mutect2, varscan2
- CAMK2B | c.1824C>T p.H608= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as rs780905919, COSV51665025; called by muse, mutect2, varscan2
- CAPN1 | c.213G>A p.K71= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV54200973; called by muse, mutect2, varscan2
- CBFA2T3 | c.1149C>A p.I383= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV51931653; called by muse, mutect2, varscan2
- CCDC88B | c.3027G>C p.G1009= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV57267665; called by muse, mutect2, varscan2
- CCNG2 | c.567G>A p.L189= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV60354556; called by muse, mutect2, varscan2
- CFAP221 | c.1530C>T p.F510= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1421592543, COSV99732617; called by muse, mutect2, varscan2
- CFAP45 | c.528C>T p.L176= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV63650509; called by muse, mutect2, varscan2
- CKAP4 | c.765C>T p.F255= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV65172530; called by muse, mutect2
- CNGA4 | c.1440G>C p.V480= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV66006848; called by muse, mutect2, varscan2
- CNTN6 | c.2970G>A p.R990= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV63186044; called by mutect2, varscan2
- COL6A2 | c.561C>G p.L187= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV56013831; called by muse, mutect2
- COPE | c.60C>T p.F20= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV53229460, COSV53232034; called by muse, mutect2, varscan2
- COX5B | c.81G>C p.A27= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV51480951, COSV51481078; called by muse, mutect2, varscan2
- CST6 | c.402C>T p.P134= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs1214085211, COSV56412906; called by muse, mutect2, varscan2
- CSTF3 | c.114C>G p.L38= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV60613764; called by muse, varscan2
- CUL3 | c.1599G>A p.E533= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV52368940; called by muse, mutect2, varscan2
- CYP4B1 | c.471C>T p.F157= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV54725481; called by muse, mutect2, varscan2
- DACH2 | c.438C>G p.L146= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV64182395; called by muse, mutect2, varscan2
- DARS2 | c.1209C>T p.F403= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- DCAF1 | c.2262C>T p.I754= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV60041483; called by muse, mutect2, varscan2
- DDO | c.730C>T p.L244= (on ENST00000368924 / NM_001368172.1; = p.L185= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV64469623, COSV64470489; called by muse, mutect2, varscan2
- DDR1 | c.2184G>A p.G728= (on ENST00000324771; = p.G691= on NM_001954.4) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1335006574, COSV100241621; called by muse, mutect2, varscan2
- DDR2 | c.259C>T p.L87= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs367836775; called by mutect2, varscan2
- DDX23 | c.2295C>T p.I765= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV56400230; called by muse, mutect2, varscan2
- DDX28 | c.36C>G p.L12= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV60106090; called by muse, mutect2, varscan2
- DDX59 | c.1359C>T p.C453= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs771570708, COSV100494565; called by muse, mutect2, varscan2
- DGUOK | c.288G>A p.L96= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51204649; called by muse, mutect2, varscan2
- DHCR24 | c.111C>G p.L37= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV64875304; called by muse, mutect2, varscan2
- DHPS | c.324C>A p.I108= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV52952955, COSV99269625; called by muse, mutect2, varscan2
- DLX4 | c.301C>T p.L101= (on ENST00000240306 / NM_138281.3; = p.L29= on NM_001934.3) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV53592648; called by muse, mutect2
- DNAH10 | c.1551C>T p.D517= (on ENST00000409039; = p.D456= on NM_207437.3) | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV68999625; called by muse, mutect2, varscan2
- DNAH3 | c.4084C>T p.L1362= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV54544739; called by muse, mutect2, varscan2
- DNAJC14 | c.159C>T p.L53= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57914034; called by muse, varscan2
- DNAJC22 | c.621C>A p.T207= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV67712746; called by muse, mutect2, varscan2
- DVL1 | c.1404G>A p.R468= (on ENST00000378888 / NM_001330311.2; = p.R443= on NM_004421.3) | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV104411950, COSV59565115; called by muse, mutect2, varscan2
- EIF5B | c.2265C>T p.L755= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV56816149; called by muse, mutect2, varscan2
- ELK3 | c.438C>T p.F146= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1347006905, COSV99957655; called by muse, mutect2, varscan2
- ENPP1 | c.477G>A p.L159= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV62935372; called by muse, mutect2, varscan2
- EPHA8 | c.1506C>G p.L502= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV51289415; called by muse, mutect2, varscan2
- EPHB3 | c.2643C>G p.L881= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs746453403, COSV57808594; called by muse, mutect2, varscan2
- EPHB4 | c.2862G>A p.L954= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV62270190; called by muse, mutect2, varscan2
- EPN1 | c.792C>T p.F264= (on ENST00000270460 / NM_001321263.1; = p.F239= on NM_013333.3) | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs1346288248, COSV50036666; called by muse, mutect2, varscan2
- EPOR | c.777C>A p.L259= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV55801335; called by mutect2, varscan2
- EPPK1 | c.3951C>T p.L1317= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs369368390; called by muse, mutect2, varscan2
- EXT1 | c.1668C>T p.I556= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV65483825; called by muse, mutect2, varscan2
- F12 | c.360C>T p.L120= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53692731; called by muse, mutect2, varscan2
- FAT4 | c.13530C>T p.I4510= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs774693839, COSV58703309; called by muse, mutect2, varscan2
- FCRL1 | c.306G>A p.Q102= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV63826942; called by muse, mutect2, varscan2
- FERMT3 | c.889C>T p.L297= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs753533257, COSV54182794; called by muse, mutect2, varscan2
- FPR2 | c.891C>T p.L297= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs772695564, COSV60674184; called by muse, mutect2, varscan2
- FRY | c.3942C>G p.L1314= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs779597055, COSV66577240; called by muse, mutect2, varscan2
- FRY | c.4545C>T p.P1515= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1317007395, COSV66577246; called by muse, mutect2, varscan2
- GALNT17 | c.1296C>T p.S432= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs766680813, COSV61184715; called by muse, mutect2, varscan2
- GCC2 | c.4416C>T p.L1472= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1430049655, COSV59179286; called by muse, mutect2, varscan2
- GCH1 | c.522C>A p.I174= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54303352; called by muse, varscan2
- GFPT1 | c.1002C>T p.I334= (on ENST00000357308 / NM_001244710.2; = p.I316= on NM_002056.4) | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV61950046; called by muse, mutect2, varscan2
- GFRA3 | c.135C>G p.L45= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs536166264, COSV51230797, COSV51231247; called by muse, mutect2, varscan2
- GJA9 | c.1356C>G p.V452= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV62532665; called by muse, mutect2, varscan2
- GK5 | c.1476G>C p.L492= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as COSV67486595; called by muse, mutect2, varscan2
- GNAT2 | c.573C>G p.V191= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV63555297; called by muse, mutect2, varscan2
- GNL1 | c.582C>T p.I194= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1002809569, COSV64835198; called by muse, mutect2
- GRIN2C | c.1989C>A p.L663= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV53117094; called by muse, mutect2, varscan2
- GRM6 | c.1881C>G p.L627= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51448457; called by muse, mutect2, varscan2
- GRPR | c.126C>T p.V42= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV66670101; called by muse, mutect2, varscan2
- H1-4 | c.153C>T p.S51= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs762056816, COSV56803170; called by muse, mutect2, varscan2
- H3-3B | c.348G>A p.K116= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV54666739; called by muse, mutect2, varscan2
- HINT1 | c.270G>C p.L90= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58343595; called by muse, mutect2, varscan2
- HOXA2 | c.348C>T p.A116= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV56067502; called by muse, mutect2, varscan2
- HSD17B13 | c.805C>T p.L269= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs990778771, COSV56347099; called by muse, varscan2
- HTR3D | c.1116C>T p.L372= (on ENST00000382489 / NM_001163646.2; = p.L197= on NM_182537.3) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs267599708, COSV61913827; called by muse, mutect2, varscan2
- HYOU1 | c.744G>A p.V248= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV68217077; called by muse, mutect2, varscan2
- IGF2BP3 | c.729G>A p.S243= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs756431557, COSV51681648; called by muse, mutect2, varscan2
- IGSF9 | c.2109C>T p.F703= (on ENST00000368094 / NM_001135050.2; = p.F687= on NM_020789.4) | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs776748563, COSV63641758; called by muse, mutect2, varscan2
- INMT | c.636C>T p.S212= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV50002468; called by muse, mutect2, varscan2
- INPP5D | c.166C>T p.L56= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV64039506; called by muse, mutect2, varscan2
- INTS7 | c.408G>A p.R136= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs780282055, COSV65345089; called by muse, mutect2, varscan2
- JPH1 | c.669T>A p.L223= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV60614044; called by muse, mutect2
- KDM1A | c.1563C>T p.L521= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs369674278; called by muse, mutect2, varscan2
- KIF1A | c.2571G>C p.L857= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV57498767; called by muse, mutect2, varscan2
- KIF1C | c.2184C>T p.I728= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV57906357; called by muse, mutect2, varscan2
- KLHDC3 | c.762T>C p.F254= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV55065510; called by muse, mutect2
- KRT86 | c.63G>C p.R21= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV53293870; called by muse, mutect2, varscan2
- LARP1 | c.3045C>T p.L1015= (on ENST00000518297 / NM_033551.3; = p.L938= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs557318389, COSV60430482; called by muse, mutect2, varscan2
- LCT | c.5418G>A p.E1806= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV51555905; called by muse, mutect2, varscan2
- LGR4 | c.1188G>A p.L396= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs149138714, COSV64865944; called by muse, mutect2, varscan2
- LILRB2 | c.141C>G p.L47= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV58744457, COSV58747760; called by muse, mutect2, varscan2
- LIMK1 | c.93G>A p.R31= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60283914; called by muse, mutect2
139 further variants in this file (0 protein-altering or splice-affecting, 116 silent, 23 other) are not listed here.
